Gene-level copy-number profile of tumor specimen HCM-SANG-0271-D12-01A-01D-A80T-32 from HCMI case HCM-SANG-0271-D12, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Tubular adenoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: GX.
Specimen HCM-SANG-0271-D12-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Premalignant.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 06942983-fcb7-43de-8d94-1e976c3d6313.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0271-D12-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/254d85f8-8746-4176-918e-006698b0a39b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 519; copy number 1: 65; copy number 2: 4,339; copy number 3: 30,998; copy number 4: 18,052; copy number 5: 3,787; copy number 6: 262; copy number 7: 24; copy number 8: 37; copy number 9: 647; copy number 11: 6; copy number 12: 41; copy number 13: 137.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,702,379–1,745,992, 4 genes (within-gene range 0–3): CDK11A, AL031282.2, AL031282.1, SLC35E2A.
- chr1:12,857,086–12,861,909, 1 gene (within-gene range 0–3): PRAMEF2.
- chr14:73,537,143–73,543,796, 2 genes (within-gene range 0–3): ACOT1, NT5CP2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 892 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:45,323,253–45,480,136, 3 genes, copy number 8: THAP12P9, AC108043.1, RNU6-931P.
- chr6:32,659,467–32,668,383, 2 genes, copy number 7: HLA-DQB1, HLA-DQB1-AS1.
- chr8:22,679,013–23,164,027, 17 genes, copy number 7: AC105046.1, EGR3, AC055854.1, AC105046.2, PEBP4, AC037441.1, AC037441.2, RN7SL303P, AC107959.1, RHOBTB2, TNFRSF10B, AC107959.2, AC107959.3, AC107959.4, AC107959.5, TNFRSF10C, TNFRSF10D.
- chr20:30,214,765–64,327,972, 870 genes, copy number 7–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 60. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
